CGCI case BLGSP-71-30-00656 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8f95b472-13b7-49eb-9636-f5e394689cd7

Demographics
Sex at birth: male; Age at index: 59 years; Vital status: Alive.

Diagnoses (2)
1. Burkitt lymphoma, NOS (Includes all variants) (the primary disease): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Small intestine, NOS; Classification of tumor: primary; Age at diagnosis: 59.9 years (21,888 days); Year of diagnosis: 2012; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage II; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,143 days (8.6 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, adult; Max tumor bulk site: Small intestine; Sites of involvement: Small intestine.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Mesenteric; Lymph nodes positive: 4; Lymph nodes tested: 4; Tumor largest dimension diameter: 12 cm.
   Pathology details: Lymph node involved site: Retroperitoneal.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-IVAC; Days to treatment start: 18 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CODOX; Days to treatment start: 18 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Doxorubicin + Etoposide + Ifosfamide + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 18 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.
2. Tumor, NOS: Tissue or organ of origin: Bladder, NOS; Classification of tumor: Synchronous primary; Age at diagnosis: 66.9 years (24,423 days); Days to diagnosis: 2,535 days (6.9 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Initial Diagnosis.

Follow-up (5 entries)
- Days to follow up: 0 days; ECOG performance status: 1.
- Days to follow up: 2,815 days (7.7 years); Disease response: Tumor Free.
- Days to follow up: 2,969 days (8.1 years); Disease response: Tumor Free.
- Days to follow up: 3,143 days (8.6 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 491.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CCND1 (IHC): Negative.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- FOXP1 (IHC): Positive.
- IRF4 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- Test (IHC): Negative; Specialized molecular test: GCET1.
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 254 [Blood test normal range upper: 240].

Other clinical attributes
- Day 0: Weight: 98.7 kg; Height: 176 cm; BMI: 31.9.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-30-00656-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Small Bowel; Preservation method: FFPE; Days to sample procurement: 0 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00656-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-30-00656-01-BCL2: Tissue microarray coordinates: C4,D4.
  Slide BLGSP-71-30-00656-01-BCL6: Tissue microarray coordinates: C4,D4.
  Slide BLGSP-71-30-00656-01-CD3: Tissue microarray coordinates: C4,D4.
  Slide BLGSP-71-30-00656-01-EBER: Tissue microarray coordinates: C4,D4.
  Slide BLGSP-71-30-00656-01-CD20: Tissue microarray coordinates: C4,D4.
  Slide BLGSP-71-30-00656-01-CD10: Tissue microarray coordinates: C4,D4.
  Slide BLGSP-71-30-00656-01-Ki67: Tissue microarray coordinates: C4,D4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 1; Lymph nodes examined: Yes.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 254; Immunophenotypic analysis method: Immunohistochemistry; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: FOXP1.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: MUM1.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: GCET1.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunophenotypic analysis tested: cyclin D1.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL2.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: Bladder; New tumor event diagnosis evidence: Biopsy with Histologic Confirmation; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 1: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: Yes.
- Treatments, Treatment: Therapy regimen: Initial; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CODOXR/IVACR(50% reduction) (Magrath protocol, M omitted); Pharma adjuvant cycles count: 4.
